Somatic mutation profile of tumor specimen TCGA-WT-AB44-01A (aliquot TCGA-WT-AB44-01A-11D-A41F-09) from TCGA case TCGA-WT-AB44, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA.
Specimen TCGA-WT-AB44-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e956ad26-81c3-44c2-8a50-18187793ed81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WT-AB44-10A (Blood Derived Normal), aliquot TCGA-WT-AB44-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2789dfe-7a08-4134-9855-7e4fdaa39afc

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 3, Intron 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 41/78 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2763G>T p.K921N | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100382664, COSV60623166; called by muse, mutect2, varscan2
- ANGPTL5 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100527653; called by muse, mutect2, varscan2
- APOA1 | c.198A>G p.L66= | Splice Region (SNP) | VAF 36/95 reads (38%) | catalogued as rs540974091, COSV99369141; called by muse, mutect2, varscan2
- BASP1 | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs895520489, COSV100493563, COSV59471134; called by muse, mutect2, varscan2
- CACNA1E | c.3357G>T p.E1119D | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100701320; called by muse, mutect2
- DCAF12L1 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV100948108; called by muse, mutect2
- FCN1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs768822524, COSV100878822, COSV65662118; called by muse, mutect2, varscan2
- LYST | c.9838C>T p.R3280* | Nonsense Mutation (SNP) | VAF 66/926 reads (7%) | catalogued as rs201694319, COSV101088333; called by muse, mutect2
- NUP210L | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55157790, COSV99667320; called by muse, mutect2, varscan2
- OSBPL1A | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs773613142, COSV100111183; called by muse, mutect2, varscan2
- PABPC3 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as rs1275142183, COSV55801360, COSV99879070; called by muse, mutect2, varscan2
- PKD2 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs144590958, COSV99416898; called by muse, mutect2, varscan2
- PLCL1 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as COSV101406804, COSV70820576; called by muse, mutect2, varscan2
- RAPGEF6 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as rs761250497, COSV57239227; called by muse, mutect2, varscan2
- SF1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57111668; called by muse, mutect2, varscan2
- SLC22A2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1314319598, COSV65266636; called by muse, mutect2, varscan2
- SLC30A3 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs567778975, COSV51985477, COSV99274025; called by muse, mutect2, varscan2
- TBX3 | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99983425; called by muse, mutect2, varscan2
- WNK1 | c.3790C>T p.P1264S (on ENST00000315939 / NM_018979.4; = p.P1017S on NM_014823.3) | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266322; called by muse, mutect2, varscan2
- ZFR2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs185400185, COSV53599530, COSV53604876; called by muse, mutect2, varscan2
- ZNF131 | c.877T>A p.C293S (on ENST00000509156 / NM_001330707.2; = p.C259S on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100185198; called by muse, mutect2, varscan2
- CDH1 | c.863_864dup p.A289Tfs*6 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.2702G>A p.G901D (on ENST00000651564; = p.G854D on NM_015692.5) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTCF | c.164del p.N55Tfs*7 | Frame Shift Del (DEL) | VAF 41/86 reads (48%) | called by mutect2, pindel, varscan2
- BSX | c.288G>A p.P96= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1264710484, COSV58005976; called by muse, mutect2, varscan2
- CALML3 | c.177C>T p.D59= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100178751; called by muse, mutect2
- KMT2B | c.7579C>T p.L2527= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99494948; called by muse, mutect2, varscan2
- PCDHB1 | c.1011G>A p.V337= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV100128012, COSV100128036; called by muse, mutect2, varscan2
- SH3TC1 | c.1101C>A p.G367= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as COSV99794460; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-849G>A | Intron (SNP) | VAF 13/93 reads (14%) | catalogued as rs144645122; called by muse, mutect2, varscan2
